TARGET case TARGET-10-PARYAJ — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5d625039-da87-4eab-a9d4-7dd6c41a09df

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Dead; Days to death: 2,697 days (7.4 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 1.2 years (425 days); Year of diagnosis: 2008; Days to last follow up: 2,697 days (7.4 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (2 entries)
- Days to follow up: 1,441 days (3.9 years); Days to first event: 1,441 days (3.9 years); First event: Relapse.
- Days to follow up: 2,697 days (7.4 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 16.9 ×10³/µL.
- Day 8: Bone Marrow blast count 3%; Minimal Residual Disease (Flow Cytometry) 2.5%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 1%.
- Day 43: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.15%.

Biospecimens (3 samples)
- Samples TARGET-10-PARYAJ-09A, TARGET-10-PARYAJ-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARYAJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- First Event: Relapse (off-therapy)
- Overall Survival Time in Days: 2697
- WBC at Diagnosis: 16.9
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 8: 2.5
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 1
- MRD Day 29 Sensitivity: 0.01
- MRD Day 43: 0.15
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: Yes
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 3
- BMA Blasts Day 29: 1
- BMA Blasts Day 43: 0
- Karyotype: 45,XY,dic(9;12)(p12;p11.2),del(18)(q21)[10]/45,XY,dic(8;9)(p11.1;p12),del(18)(q21)[2]/46,XY[8]
- DNA Index: 1
- Alternate Therapy: Chemotherapy; Radiation (NOS); Transplant
- Cell of Origin: B-Precursor
